Gene-level copy-number profile of tumor specimen ALCH-B1XE-TTP1-A from ALCHEMIST case ALCH-B1XE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,424 days).
Specimen ALCH-B1XE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 64ac7302-86bc-4318-b95d-1ec530acf84a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ff595d6a-2e6b-4093-8153-accdba7842f6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 149; copy number 2: 57,919; copy number 3: 238; copy number 4: 15; copy number 5: 19; copy number 6: 2; copy number 8: 1; copy number 9: 3; copy number 13: 1; copy number 23: 2; copy number 24: 5.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,466,699–212,472,905, 1 gene: LINC02771.
- chr10:33,023,368–33,035,664, 3 genes (within-gene range 0–2): MTND4LP11, RN7SL847P, AL365203.1.
- chr10:48,546,472–48,546,713, 1 gene (within-gene range 0–2): AC016397.1.
- chr10:63,902,451–63,903,245, 1 gene (within-gene range 0–2): RPL7AP50.
- chr11:119,149,052–119,162,653, 1 gene: ABCG4.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:21,563,819–21,580,076, 2 genes: RBBP4P5, OR10G3.
- chr15:23,430,839–23,435,212, 1 gene: HERC2P6.
- chr15:25,169,337–25,211,877, 24 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr19:41,998,321–42,081,552, 2 genes: GRIK5, ZNF574.
- chr19:45,076,510–45,092,635, 2 genes (within-gene range 0–2): GEMIN7-AS1, GEMIN7.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.
- chr21:44,347,767–44,348,295, 1 gene: AP001063.1.
- chr22:21,290,760–21,294,586, 1 gene (within-gene range 0–3): BCRP6.
- chr22:23,510,154–23,513,602, 2 genes: AP000345.3, LINC02557.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,073,909–228,076,550, 1 gene, copy number 9: LINC02809.
- chr2:131,218,067–131,265,278, 2 genes, copy number 5 (within-gene range 2–5): POTEE, RNU6-127P.
- chr11:1,947,278–2,141,238, 8 genes, copy number 5–24 (within-gene range 2–24): MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, IGF2.
- chr11:2,129,121–2,129,964, 1 gene, copy number 5: AC132217.1.
- chr11:2,134,134–2,134,209, 1 gene, copy number 5 (within-gene range 2–5): MIR483.
- chr14:105,647,924–105,669,843, 2 genes, copy number 5 (within-gene range 2–5): COPDA1, IGHGP.
- chr15:23,439,038–23,447,243, 1 gene, copy number 6: GOLGA6L2.
- chr17:7,235,029–7,266,166, 9 genes, copy number 5: PHF23, GABARAP, AC120057.2, AC120057.3, CTDNEP1, AC003688.1, ELP5, CLDN7, Y_RNA.
- chr17:46,503,946–46,555,650, 2 genes, copy number 5 (within-gene range 3–5): RDM1P2, LRRC37A2.
- chr17:46,537,534–46,537,814, 1 gene, copy number 5 (within-gene range 3–5): RN7SL199P.
- chr19:1,508,023–1,536,046, 1 gene, copy number 6 (within-gene range 2–6): PLK5.
- chr21:44,107,373–44,210,114, 2 genes, copy number 8–13 (within-gene range 2–13): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 9: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 149. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
